Somatic mutation profile of tumor specimen TCGA-BG-A222-01A (aliquot TCGA-BG-A222-01A-11D-A159-09) from TCGA case TCGA-BG-A222, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 49.9 years (18,220 days).
Specimen TCGA-BG-A222-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7c0d4ea-4d78-4160-894e-84d848ae86e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A222-10A (Blood Derived Normal), aliquot TCGA-BG-A222-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85c238cb-6a1f-41d1-bd86-aff9c72e9fd7

The open-access MAF lists 5,460 somatic variants for this specimen: 3,955 protein-altering or splice-affecting, 1,358 silent, 147 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,265, Silent 1,358, Frame Shift Del 304, Nonsense Mutation 116, Frame Shift Ins 97, Splice Site 87, Intron 62, Splice Region 62, RNA 33, 3'UTR 18, 5'Flank 15, In Frame Del 13.

Variants (750 of 5,460; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.2187dup p.R730Tfs*5 | Frame Shift Ins (INS) | VAF 17/52 reads (33%) | catalogued as rs1555809987; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 30/49 reads (61%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- CDKN2A | c.457+1G>T p.X153_splice | Splice Site (SNP) | VAF 21/46 reads (46%) | hotspot (GDC flag); catalogued as CS041518, CS941435, COSV58685123, COSV58690553, COSV58696311; called by muse, varscan2
- COL18A1 | c.3363dup p.G1122Rfs*23 (on ENST00000359759 / NM_130444.3; = p.G887Rfs*23 on NM_030582.4) | Frame Shift Ins (INS) | VAF 9/31 reads (29%) | catalogued as rs775168204; ClinVar: pathogenic; called by mutect2, varscan2
- COL7A1 | c.682+1G>A p.X228_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as rs775288140, CS072163, CS971697, COSV100096307; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- DYRK1A | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as rs886041291, CM162571, COSV58293451; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- F8 | c.5399G>A p.R1800H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs137852442, CM066566, CM1314174, CM910139, COSV100811547; ClinVar: pathogenic; called by muse, mutect2
- GALC | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs766310671, CM062751, COSV99729746; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- INPP5B | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); catalogued as rs773387490, COSV65958115; ClinVar: likely pathogenic; called by muse, mutect2
- KCNQ3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs118192251, CM081318, COSV101196138; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- NBAS | c.2950del p.I984Lfs*8 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs776797592; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NR5A1 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs104894125, CM071047, COSV101007691; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs573607437; ClinVar: pathogenic; called by pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PKD2 | c.2159dup p.N720Kfs*5 | Frame Shift Ins (INS) | VAF 16/32 reads (50%) | catalogued as rs757757289; ClinVar: pathogenic; called by mutect2, varscan2
- PTCH1 | c.2626G>T p.G876* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as rs1131691758, COSV100108660; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 26/43 reads (60%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SF3B4 | c.1147del p.H383Mfs*75 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs387907186, CD123383; ClinVar: pathogenic; called by pindel, varscan2
- VWF | c.2435del p.P812Rfs*31 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs62643632, CD920917, CM074633, COSV54614968; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2M | c.2084A>G p.Y695C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.375); catalogued as COSV100588687; called by muse, mutect2, varscan2
- A2ML1 | c.3915G>T p.Q1305H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV100228943; called by muse, mutect2, varscan2
- AACS | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV99908015; called by muse, mutect2, varscan2
- AAK1 | c.2618A>G p.N873S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as COSV101275967; called by muse, mutect2, varscan2
- AARS1 | c.2222C>T p.T741M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs148383122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AASDH | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99221300; called by muse, mutect2, varscan2
- AATK | c.2815T>C p.Y939H (on ENST00000326724 / NM_001080395.3; = p.Y836H on NM_004920.2) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100352821; called by muse, mutect2, varscan2
- ABCA1 | c.2849T>C p.F950S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs75972547, COSV101036976; called by muse, varscan2
- ABCA12 | c.1201T>C p.S401P (on ENST00000272895 / NM_173076.3; = p.S83P on NM_015657.3) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as rs747544761, COSV99790035; called by muse, mutect2, varscan2
- ABCA12 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99790039; called by muse, mutect2
- ABCA13 | c.12889G>A p.D4297N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV101291346; called by muse, mutect2, varscan2
- ABCA2 | c.6799C>T p.R2267C (on ENST00000614293; = p.R2237C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV99687659; called by muse, mutect2, varscan2
- ABCA2 | c.2798A>G p.D933G (on ENST00000614293; = p.D903G on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99687662; called by muse, mutect2, varscan2
- ABCA2 | c.2488T>C p.F830L (on ENST00000614293; = p.F800L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.781); catalogued as COSV99687664; called by muse, varscan2
- ABCA2 | c.2434C>A p.H812N (on ENST00000614293; = p.H782N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99687665; called by muse, varscan2
- ABCA3 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV100068503; called by muse, mutect2, varscan2
- ABCA3 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as rs201341756, COSV100068505; called by muse, mutect2, varscan2
- ABCA4 | c.4350T>C p.L1450= | Splice Region (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100933126; called by muse, mutect2, varscan2
- ABCA4 | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1216408517, COSV64675475; called by muse, mutect2, varscan2
- ABCA6 | c.96+2T>A p.X32_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99446501; called by muse, mutect2, varscan2
- ABCA7 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs564544240, COSV99565811; called by muse, mutect2, varscan2
- ABCA7 | c.3028G>A p.V1010M | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs766698472, COSV54025946; called by muse, mutect2, varscan2
- ABCA8 | c.1036T>C p.F346L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.253); catalogued as COSV99285831; called by muse, mutect2, varscan2
- ABCB10 | c.1389del p.R464Afs*20 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs1406695210; called by mutect2, pindel, varscan2
- ABCB4 | c.1890G>A p.M630I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs760418164, COSV99710472; called by muse, mutect2, varscan2
- ABCB5 | c.2617G>A p.A873T (on ENST00000404938 / NM_001163941.2; = p.A428T on NM_178559.6) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs372997293; called by muse, mutect2, varscan2
- ABCB9 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV99757729; called by muse, varscan2
- ABCC1 | c.1944T>A p.N648K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as COSV100579582; called by muse, mutect2, varscan2
- ABCC1 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100579584; called by muse, mutect2, varscan2
- ABCC2 | c.2908T>C p.Y970H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372803066; called by muse, mutect2, varscan2
- ABCC3 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99559178; called by muse, mutect2, varscan2
- ABCC3 | c.3893A>G p.Y1298C | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99559180; called by muse, mutect2
- ABCC4 | c.3835G>A p.A1279T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV65319379; called by muse, mutect2, varscan2
- ABCC5 | c.3640T>C p.S1214P | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV99656928; called by muse, mutect2, varscan2
- ABCC8 | c.95A>G p.N32S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.354); catalogued as COSV56847614; called by muse, mutect2, varscan2
- ABCD2 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs778993146, COSV100429493; called by muse, mutect2, varscan2
- ABCF2 | c.40_42del p.K14del | In Frame Del (DEL) | VAF 24/78 reads (31%) | catalogued as rs1563620205; called by pindel, varscan2
- ABCG5 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as rs530616214, COSV99575399; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); catalogued as COSV99865409; called by muse, mutect2, varscan2
- ABHD8 | c.868A>T p.I290F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV99917270; called by muse, mutect2, varscan2
- ABR | c.2485G>A p.A829T (on ENST00000302538 / NM_021962.5; = p.A792T on NM_001092.5) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as COSV99347985; called by muse, mutect2, varscan2
- ABTB1 | c.1432T>C p.C478R (on ENST00000232744 / NM_172027.3; = p.C336R on NM_032548.3) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99229829; called by muse, mutect2, varscan2
- AC005833.1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs373419543, COSV52899928; called by muse, mutect2, varscan2
- AC005833.1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0); catalogued as rs1374451872, COSV99362773; called by muse, mutect2, varscan2
- AC098582.1 | c.174T>A p.C58* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as COSV99985614; called by muse, mutect2, varscan2
- AC244197.3 | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as CM128190, CM141180, COSV100558013; called by muse, mutect2, varscan2
- ACACB | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780343613, COSV100622914; called by muse, mutect2, varscan2
- ACACB | c.5942del p.G1981Vfs*77 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | catalogued as COSV58148007; called by mutect2, pindel, varscan2
- ACADM | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as CM125805, COSV100273478; called by muse, mutect2, varscan2
- ACAN | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV61359470; called by muse, mutect2, varscan2
- ACAN | c.4388C>T p.A1463V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.843); catalogued as rs369619909; called by muse, mutect2, varscan2
- ACAN | c.5210G>A p.G1737E | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV100718137; called by muse, mutect2, varscan2
- ACAP2 | c.770T>C p.L257S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.434); catalogued as COSV100462119, COSV100462480; called by muse, mutect2, varscan2
- ACKR3 | c.743A>T p.H248L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV99799574; called by muse, mutect2, varscan2
- ACLY | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100709700; called by muse, mutect2, varscan2
- ACO1 | c.2177A>G p.N726S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100008143; called by muse, mutect2, varscan2
- ACOX1 | c.107T>A p.I36N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV99503598; called by muse, mutect2, varscan2
- ACSBG1 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99357409; called by muse, mutect2, varscan2
- ACSF3 | c.1414A>T p.T472S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV100441342; called by muse, mutect2, varscan2
- ACSL6 | c.1555T>C p.Y519H (on ENST00000379240; = p.Y544H on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99733710; called by muse, mutect2, varscan2
- ACTA1 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as CM041998, COSV100796741; called by muse, mutect2, varscan2
- ACTG1 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59510993; called by muse, mutect2, varscan2
- ACTR5 | c.1294-1G>A p.X432_splice | Splice Site (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99710041; called by muse, mutect2, varscan2
- ACTR8 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs988976011, COSV99213704; called by muse, varscan2
- ACVR1C | c.628T>C p.W210R | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1465646651, COSV99694703; called by muse, mutect2
- ACVRL1 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66360620; called by muse, mutect2, varscan2
- ADA2 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52834257; called by muse, mutect2, varscan2
- ADAM10 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs768279822, COSV99546104; called by muse, mutect2, varscan2
- ADAM21 | c.1943A>G p.K648R | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV99961021; called by muse, mutect2, varscan2
- ADAM22 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV55980410; called by muse, mutect2, varscan2
- ADAM22 | c.536A>G p.Q179R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99716986; called by muse, mutect2, varscan2
- ADAM23 | c.2111A>T p.D704V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52225760; called by muse, mutect2, varscan2
- ADAM28 | c.1546T>C p.C516R | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99738730; called by muse, mutect2, varscan2
- ADAM28 | c.2129A>T p.H710L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV99738735; called by muse, mutect2, varscan2
- ADAM29 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100822018; called by muse, mutect2, varscan2
- ADAM29 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100822019, COSV63663358; called by muse, mutect2, varscan2
- ADAM29 | c.1886T>C p.F629S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.391); catalogued as COSV100822020; called by muse, mutect2, varscan2
- ADAM30 | c.1664G>A p.G555D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101023873; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as COSV99836068; called by muse, mutect2, varscan2
- ADAMTS13 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV100747089; called by muse, mutect2, varscan2
- ADAMTS16 | c.2900C>T p.A967V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.334); catalogued as COSV99068532, COSV99941269; called by muse, mutect2, varscan2
- ADAMTS17 | c.1388A>T p.H463L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV99170703; called by muse, mutect2, varscan2
- ADAMTS18 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99272693; called by muse, mutect2, varscan2
- ADAMTS2 | c.2209+1G>T p.X737_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99282266; called by muse, mutect2, varscan2
- ADAMTS2 | c.2081G>A p.C694Y | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99282269; called by muse, mutect2, varscan2
- ADAMTS8 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.271); catalogued as COSV99960986; called by muse, mutect2, varscan2
- ADAMTSL1 | c.53T>C p.F18S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99442788; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1514T>C p.L505S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.193); catalogued as COSV99442794; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225728630, COSV99442798; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3152A>G p.N1051S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs1319422383, COSV101001855; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3164T>C p.F1055S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99718931; called by muse, mutect2, varscan2
- ADCK5 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58233758; called by muse, mutect2, varscan2
- ADCY10 | c.2311T>C p.Y771H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100896863; called by muse, mutect2, varscan2
- ADCY10 | c.1532T>C p.V511A | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.183); catalogued as COSV100896865; called by muse, mutect2, varscan2
- ADCY4 | c.2009C>T p.T670I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV100156579; called by muse, mutect2, varscan2
- ADCY6 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs368792367, COSV57168537; called by muse, mutect2, varscan2
- ADD3 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.61); PolyPhen probably damaging (1); catalogued as COSV99523417; called by muse, mutect2, varscan2
- ADGRB2 | c.2293G>A p.V765M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99926269; called by muse, mutect2, varscan2
- ADGRB3 | c.2603A>G p.E868G | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as COSV99485118; called by muse, mutect2, varscan2
- ADGRB3 | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99485120; called by muse, mutect2, varscan2
- ADGRD1 | c.320T>C p.F107S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99894101; called by muse, mutect2
- ADGRE1 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as COSV99165303; called by muse, mutect2, varscan2
- ADGRE1 | c.2569A>G p.R857G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV99165308; called by muse, mutect2, varscan2
- ADGRF3 | c.1267A>G p.I423V (on ENST00000311519 / NM_001145168.1; = p.I224V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs374663124; called by muse, mutect2, varscan2
- ADGRF3 | c.446C>T p.A149V (on ENST00000311519 / NM_001145168.1; = p.A90V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as COSV100275063; called by muse, mutect2, varscan2
- ADGRF4 | c.362A>T p.D121V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99348410; called by muse, mutect2, varscan2
- ADGRG4 | c.6059C>T p.P2020L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144593814, COSV54956744, COSV99796699; called by muse, mutect2, varscan2
- ADGRL1 | c.1102T>C p.F368L (on ENST00000340736 / NM_001008701.3; = p.F363L on NM_014921.5) | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV100529537; called by muse, mutect2, varscan2
- ADGRL3 | c.2762A>G p.H921R (on ENST00000506720 / NM_001322402.2; = p.H853R on NM_015236.6) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101547135; called by muse, mutect2, varscan2
- ADGRV1 | c.10055T>C p.V3352A | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV101316001; called by muse, mutect2, varscan2
- ADGRV1 | c.15335G>A p.R5112H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs142891862; called by muse, varscan2
- ADGRV1 | c.15989T>C p.V5330A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV101316003; called by muse, mutect2, varscan2
- ADH1A | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99265789; called by muse, mutect2, varscan2
- ADIPOR1 | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as COSV100579542; called by muse, mutect2, varscan2
- ADO | c.259T>A p.Y87N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101060454; called by muse, mutect2, varscan2
- ADRA2A | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749168689, COSV99701647; called by muse, mutect2, varscan2
- ADRA2B | c.652T>A p.S218T | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.55); PolyPhen benign (0.043); catalogued as COSV101337364; called by muse, mutect2, varscan2
- AEBP1 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as rs934991572, COSV99788786; called by muse, mutect2, varscan2
- AFAP1 | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100631534; called by muse, mutect2, varscan2
- AFAP1L1 | c.2176A>T p.N726Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV99695545; called by muse, mutect2, varscan2
- AFF3 | c.1255A>G p.S419G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs760333652, COSV57842263; called by muse, mutect2, varscan2
- AFM | c.717T>A p.Y239* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99888840; called by muse, mutect2, varscan2
- AGAP1 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs773218170, COSV58319853, COSV58340917; called by muse, mutect2, varscan2
- AGAP1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100365218; called by muse, mutect2, varscan2
- AGAP1 | c.1699C>T p.H567Y (on ENST00000304032 / NM_001037131.3; = p.H514Y on NM_014914.5) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100365219; called by muse, mutect2, varscan2
- AGAP6 | c.1360G>T p.A454S (on ENST00000374056 / NM_001365867.1; = p.A477S on NM_001077665.2) | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100929090; called by muse, mutect2, varscan2
- AGBL2 | c.2204T>C p.I735T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as rs140006264; called by muse, varscan2
- AGFG1 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV100028785; called by muse, mutect2, varscan2
- AGMO | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1438899109, COSV100694172; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AGPAT3 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV52373638, COSV99377459; called by muse, mutect2, varscan2
- AGPAT3 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as rs556642534, COSV99377461; called by muse, mutect2, varscan2
- AGPAT3 | c.942G>A p.W314* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV52370470, COSV99377464; called by muse, mutect2, varscan2
- AGTPBP1 | c.3560A>G p.Y1187C (on ENST00000357081 / NM_001330701.2; = p.Y1147C on NM_015239.2) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100429772; called by muse, mutect2, varscan2
- AHCTF1 | c.3966G>T p.E1322D (on ENST00000366508; = p.E1296D on NM_015446.5) | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100403726; called by muse, mutect2, varscan2
- AHCTF1 | c.3446T>A p.I1149N (on ENST00000366508; = p.I1123N on NM_015446.5) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as COSV100403729; called by muse, mutect2, varscan2
- AHCYL2 | c.641T>C p.L214S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100273408; called by muse, mutect2, varscan2
- AHI1 | c.3400A>G p.I1134V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99662777; called by muse, mutect2, varscan2
- AHNAK | c.11214G>A p.M3738I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV99947540; called by muse, mutect2, varscan2
- AHNAK | c.9871C>T p.P3291S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs765875422, COSV99947541; called by muse, mutect2, varscan2
- AHNAK2 | c.12067G>A p.A4023T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as rs200136053, COSV100317552; called by muse, mutect2, varscan2
- AIFM1 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as COSV99781030; called by muse, mutect2, varscan2
- AIM2 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100931073; called by muse, mutect2
- AJAP1 | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs370644922, COSV100981728; called by muse, mutect2, varscan2
- AK9 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs765848267, COSV53424456; called by muse, mutect2, varscan2
- AKAP1 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1344735368, COSV100027711; called by muse, mutect2, varscan2
- AKAP11 | c.495A>T p.Q165H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99213933; called by muse, mutect2, varscan2
- AKAP12 | c.3307A>G p.T1103A | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV99483261; called by muse, mutect2, varscan2
- AKAP13 | c.7388G>A p.R2463Q (on ENST00000394518 / NM_007200.5; = p.R2467Q on NM_006738.6) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs140687997, COSV63450170; called by muse, mutect2, varscan2
- AKAP17A | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as rs1303400747, COSV100002251; called by muse, mutect2, varscan2
- AKAP6 | c.608A>T p.D203V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99800953; called by muse, mutect2, varscan2
- AKAP8L | c.1307T>G p.V436G | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101275797; called by muse, mutect2, varscan2
- AKIP1 | c.633A>G p.*211Wext*2 | Nonstop Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100214924; called by muse, mutect2, varscan2
- AKIRIN2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV100005208, COSV57636685; called by muse, mutect2, varscan2
- AKR1C2 | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV101060469; called by muse, mutect2, varscan2
- AKR1D1 | c.262-2A>G p.X88_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99653080; called by muse, mutect2, varscan2
- AKT2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100251621; called by muse, mutect2, varscan2
- AKT2 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as rs1280863854, COSV100251622; called by muse, mutect2, varscan2
- AKTIP | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV100043651; called by muse, mutect2, varscan2
- ALDH1A2 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV99990744; called by muse, mutect2, varscan2
- ALDH2 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99922964; called by muse, mutect2, varscan2
- ALDH3A2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as rs779945294, COSV51566168; called by muse, mutect2, varscan2
- ALDOB | c.233T>A p.I78N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100878869; called by muse, mutect2, varscan2
- ALG13 | c.2149T>C p.F717L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.197); catalogued as COSV99322273; called by muse, mutect2, varscan2
- ALKBH6 | c.305T>C p.V102A (on ENST00000252984 / NM_001297701.2; = p.V130A on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99431073; called by muse, mutect2, varscan2
- ALPK2 | c.4909A>G p.I1637V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100864407; called by muse, mutect2, varscan2
- ALPP | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV101235147; called by muse, mutect2, varscan2
- AMBRA1 | c.1931G>T p.R644M (on ENST00000458649 / NM_001367468.1; = p.R554M on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV100094011; called by muse, mutect2, varscan2
- AMDHD2 | c.1225C>T p.Q409* (on ENST00000293971 / NM_001330449.2; = p.Q439* on NM_015944.4) | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as rs767632861, COSV53551904; called by muse, mutect2
- AMER1 | c.1979G>A p.G660D | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV57659396; called by muse, mutect2, varscan2
- AMOTL2 | c.865A>G p.S289G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99998176; called by muse, mutect2, varscan2
- AMPD2 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs935098442, COSV99857744; called by muse, mutect2, varscan2
- AMZ1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs774941672, COSV56688354; called by muse, varscan2
- ANAPC5 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV99946203; called by muse, mutect2, varscan2
- ANAPC5 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99946205; called by muse, mutect2
- ANK1 | c.1409A>G p.D470G | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV99225336; called by muse, mutect2, varscan2
- ANK2 | c.8446G>T p.G2816C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); catalogued as COSV100001733; called by muse, mutect2, varscan2
- ANK3 | c.6439A>G p.T2147A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99780069; called by muse, mutect2, varscan2
- ANK3 | c.2473A>G p.T825A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99780070; called by muse, mutect2, varscan2
- ANK3 | c.1973A>G p.N658S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.416); catalogued as rs1474901386, COSV99780072; called by muse, mutect2, varscan2
- ANKFN1 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100593500; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3853G>A p.A1285T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99783374; called by muse, mutect2, varscan2
- ANKRD11 | c.5005C>T p.H1669Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV99969364; called by muse, mutect2, varscan2
- ANKRD20A4P | c.2182A>T p.N728Y | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV100628552; called by muse, mutect2, varscan2
- ANKRD28 | c.2123A>T p.H708L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV101080664; called by muse, mutect2, varscan2
- ANKS1A | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as COSV100832454; called by muse, mutect2, varscan2
- ANLN | c.2975T>C p.I992T | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99732330; called by muse, mutect2, varscan2
- ANP32D | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99874317; called by muse, mutect2, varscan2
- AP1M2 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140854; called by muse, mutect2, varscan2
- AP2B1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); catalogued as COSV99251274; called by muse, mutect2, varscan2
- AP3S2 | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs538209457, COSV100318509; called by muse, mutect2, varscan2
- AP4E1 | c.2785G>A p.V929M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as rs1204722292, COSV99956658; called by muse, mutect2, varscan2
- AP5Z1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs577396839, COSV100804134; called by muse, mutect2, varscan2
- AP5Z1 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.3); catalogued as rs542054269, COSV62242022; called by muse, mutect2, varscan2
- AP5Z1 | c.925A>G p.N309D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs758467988, COSV100804136; called by muse, mutect2, varscan2
- APBA1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1441171786, COSV55228784; called by muse, mutect2, varscan2
- APBA3 | c.1166G>A p.S389N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV99516105; called by muse, mutect2
- APBB1 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs757422847, COSV100194045; called by muse, mutect2, varscan2
- APC2 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99279458; called by muse, mutect2, varscan2
- APCDD1 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1036419184, COSV100789963; called by muse, mutect2, varscan2
- APCS | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99661329; called by muse, mutect2, varscan2
- APLF | c.1043G>A p.S348N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV58145151; called by muse, mutect2, varscan2
- APLNR | c.961A>T p.T321S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV99951453; called by muse, mutect2, varscan2
- APOB | c.7631G>T p.S2544I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as COSV99265705; called by muse, mutect2, varscan2
- APOBEC2 | c.443T>A p.L148H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.221); catalogued as COSV99775377; called by muse, mutect2, varscan2
- APOBEC3B | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.481); catalogued as COSV100213777; called by muse, mutect2
- APOL2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99969128; called by muse, mutect2, varscan2
- APOL2 | c.386T>C p.I129T | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV99969129; called by muse, mutect2, varscan2
- AQP12A | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV100538638; called by muse, mutect2, varscan2
- ARAP1 | c.2842del p.A948Pfs*25 (on ENST00000393609 / NM_001040118.2; = p.A703Pfs*25 on NM_015242.4) | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as COSV61991309; called by mutect2, pindel, varscan2
- ARC | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as rs1439783366, COSV63078952; called by muse, mutect2
- AREL1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs370475152; called by muse, mutect2, varscan2
- ARFGAP1 | c.434T>C p.M145T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100796681; called by muse, mutect2, varscan2
- ARFGEF2 | c.4111T>C p.W1371R | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64212661; called by muse, mutect2, varscan2
- ARHGAP22 | c.1833C>A p.C611* | Nonsense Mutation (SNP) | VAF 36/82 reads (44%) | catalogued as COSV99985285; called by muse, mutect2, varscan2
- ARHGAP26 | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99190958; called by muse, mutect2, varscan2
- ARHGAP31 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99957138; called by muse, mutect2, varscan2
- ARHGAP31 | c.3920G>A p.C1307Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV99957139; called by muse, mutect2, varscan2
- ARHGAP36 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99357718; called by muse, mutect2, varscan2
- ARHGAP39 | c.1841A>G p.N614S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99431349; called by muse, mutect2, varscan2
- ARHGAP39 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99431352; called by muse, mutect2, varscan2
- ARHGAP45 | c.1618T>C p.Y540H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57429435; called by muse, mutect2, varscan2
- ARHGEF1 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100529018; called by muse, mutect2, varscan2
- ARHGEF1 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100529019; called by muse, mutect2, varscan2
- ARHGEF1 | c.2576G>A p.G859D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs782700907, COSV100529020, COSV61529787; called by muse, mutect2, varscan2
- ARHGEF10L | c.2936G>A p.S979N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.738); catalogued as COSV99392930; called by muse, mutect2, varscan2
- ARHGEF11 | c.2756A>G p.Y919C | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as rs1041459347, COSV100168626; called by muse, mutect2, varscan2
- ARHGEF11 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV100810115, COSV63812113; called by muse, mutect2, varscan2
- ARHGEF12 | c.3149T>C p.L1050S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100754931; called by muse, mutect2, varscan2
- ARHGEF12 | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as rs1486039186, COSV100754663; called by muse, mutect2, varscan2
- ARHGEF15 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV100730049; called by muse, mutect2, varscan2
- ARHGEF2 | c.245C>T p.T82I (on ENST00000361247 / NM_001162383.2; = p.T55I on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100560610; called by muse, mutect2, varscan2
- ARHGEF26 | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV100726561; called by muse, mutect2, varscan2
- ARHGEF4 | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV100388150; called by muse, mutect2, varscan2
- ARID1A | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs776238347, COSV61383733; called by muse, mutect2, varscan2
- ARID3C | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV99426883; called by muse, mutect2, varscan2
- ARID4A | c.2776A>G p.T926A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100794274; called by muse, mutect2, varscan2
- ARID4B | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as COSV99935638; called by muse, mutect2, varscan2
- ARIH1 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101158704; called by muse, mutect2, varscan2
- ARL3 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.328); catalogued as rs757334225, COSV99589054; called by muse, mutect2, varscan2
- ARMC3 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs1021320309, COSV53067927; called by muse, mutect2, varscan2
- ARMC4 | c.1142+2T>C p.X381_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | catalogued as rs1248126911, COSV99518603; called by muse, mutect2, varscan2
- ARNT | c.25+2T>C p.X9_splice | Splice Site (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100591186; called by muse, mutect2, varscan2
- ARNT2 | c.181A>G p.S61G | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100309038; called by muse, mutect2, varscan2
- ARPC2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1348826847, COSV55285318; called by muse, mutect2, varscan2
- ARR3 | c.200T>A p.I67N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV100330884; called by muse, mutect2, varscan2
- ARRB1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100758135; called by muse, mutect2, varscan2
- ARSD | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.158); catalogued as COSV99472157; called by muse, mutect2, varscan2
- ARSI | c.809T>C p.M270T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV100155981; called by muse, mutect2
- ARSI | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.103); catalogued as rs780152906, COSV100155982; called by muse, mutect2, varscan2
- ARSK | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs1258175979, COSV101187545; called by muse, mutect2, varscan2
- ART5 | c.688T>C p.F230L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100731646, COSV100731743; called by muse, mutect2, varscan2
- ASB6 | c.635_636del p.T212Sfs*11 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs754053598; called by pindel, varscan2
- ASCC3 | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745525921, COSV100225733; called by muse, mutect2, varscan2
- ASF1B | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs758101896, COSV99654305; called by muse, mutect2, varscan2
- ASH1L | c.4281G>A p.M1427I | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.117); catalogued as COSV100853425; called by muse, mutect2, varscan2
- ASIC3 | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99874411; called by muse, mutect2, varscan2
- ASIC4 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100761575; called by muse, mutect2, varscan2
- ASMTL | c.1297C>T p.H433Y | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV101187771; called by muse, varscan2
- ASMTL | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.868); catalogued as COSV101187772; called by muse, mutect2, varscan2
- ASPHD1 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100435430; called by muse, mutect2
- ASPM | c.5251C>T p.Q1751* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as COSV99660384; called by muse, mutect2, varscan2
- ASPN | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV65015858; called by muse, mutect2, varscan2
- ASTN1 | c.2560A>G p.N854D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99921745; called by muse, mutect2, varscan2
- ATAD5 | c.5267T>C p.V1756A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100035124; called by muse, mutect2, varscan2
- ATAT1 | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99457730; called by muse, mutect2, varscan2
- ATF2 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV99908716; called by muse, mutect2, varscan2
- ATF6 | c.1778T>C p.I593T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100909219; called by muse, mutect2, varscan2
- ATF7IP2 | c.1703A>G p.D568G | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.843); catalogued as COSV100202627; called by muse, mutect2, varscan2
- ATG16L1 | c.1108A>G p.T370A (on ENST00000392017 / NM_030803.7; = p.T351A on NM_017974.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61468292, COSV61468423; called by muse, mutect2, varscan2
- ATG2A | c.4959C>G p.S1653R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101034370; called by muse, mutect2
- ATG2A | c.2237G>A p.S746N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.056); catalogued as rs1354005701, COSV101034376; called by muse, mutect2, varscan2
- ATG2A | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.388); catalogued as COSV101034379; called by muse, mutect2, varscan2
- ATG4D | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274971802, COSV100470135; called by muse, mutect2, varscan2
- ATM | c.2588A>G p.D863G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99589676; called by muse, mutect2, varscan2
- ATM | c.5351A>G p.N1784S | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53751607; called by muse, mutect2, varscan2
- ATM | c.7043C>T p.T2348M | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99589678; called by muse, mutect2, varscan2
- ATN1 | c.1408T>C p.S470P | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.291); catalogued as COSV100755795; called by muse, mutect2, varscan2
- ATP10B | c.3070T>C p.S1024P | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100515017; called by muse, mutect2, varscan2
- ATP11A | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV99368545; called by muse, mutect2, varscan2
- ATP11A | c.3220C>T p.P1074S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99368549; called by muse, varscan2
- ATP11A | c.3242T>C p.L1081P | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99368553; called by muse, varscan2
- ATP13A1 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99366169; called by muse, mutect2, varscan2
- ATP13A4 | c.3547T>C p.S1183P | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.374); catalogued as rs1420605516, COSV100710376; called by muse, varscan2
- ATP1A2 | c.1457A>G p.Y486C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100767845; called by muse, mutect2, varscan2
- ATP1B1 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100891037; called by muse, mutect2, varscan2
- ATP23 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100274453; called by muse, mutect2, varscan2
- ATP2A2 | c.1301A>G p.Y434C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100428616; called by muse, mutect2, varscan2
- ATP2B4 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100397516; called by muse, mutect2, varscan2
- ATP2C2 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.59); catalogued as rs368339547; called by muse, mutect2, varscan2
- ATP5MF | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs762526939, COSV99461739; called by muse, mutect2, varscan2
- ATP6V0A2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs1389319438, COSV100315222; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2386C>T p.L796F | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100377015; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1050G>A p.M350I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99314130; called by muse, mutect2, varscan2
- ATP8A1 | c.2915G>A p.G972E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100046236; called by muse, mutect2, varscan2
- ATP8B2 | c.143G>A p.R48K (on ENST00000672630; = p.R15K on NM_001005855.2) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100527987; called by muse, mutect2, varscan2
- ATP8B2 | c.407G>A p.R136H (on ENST00000672630; = p.R103H on NM_001005855.2) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1197080499, COSV100527989; called by muse, mutect2, varscan2
- ATP8B4 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV52716184; called by muse, mutect2, varscan2
- ATPSCKMT | c.116T>C p.L39S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV99725863; called by muse, mutect2, varscan2
- ATR | c.7676A>G p.H2559R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1206972227, COSV100638248; called by muse, mutect2, varscan2
- ATR | c.6196C>T p.R2066W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as rs369309229; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- ATRN | c.738T>G p.S246R | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99497188; called by muse, mutect2, varscan2
- ATRX | c.2626T>C p.S876P | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100970799; called by muse, mutect2, varscan2
- AUTS2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs762540993, COSV100717076; called by muse, mutect2, varscan2
- AZIN1 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100457560; called by muse, mutect2, varscan2
- B3GALT2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs767764174, COSV66463911; called by muse, mutect2, varscan2
- B3GAT1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100437767; called by muse, mutect2, varscan2
- B3GNT8 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs201625948, COSV99524584; called by muse, mutect2, varscan2
- B3GNT9 | c.1200G>A p.W400* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs776111111, COSV99531369; called by muse, mutect2, varscan2
- B4GALNT1 | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV100247142; called by muse, mutect2, varscan2
- BACE1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV100475049; called by muse, mutect2, varscan2
- BACH1 | c.250T>C p.F84L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99728267; called by muse, mutect2, varscan2
- BAG5 | c.62A>G p.K21R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV99914856; called by muse, mutect2, varscan2
- BAK1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs761926026, COSV100645855; called by muse, mutect2, varscan2
- BBS12 | c.617T>A p.V206D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100044950; called by muse, mutect2, varscan2
- BCAM | c.600A>G p.P200= | Splice Region (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99538723; called by muse, mutect2
- BCAN | c.1952T>C p.V651A | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.096); catalogued as rs956264317, COSV100228100; called by muse, mutect2, varscan2
- BCKDHB | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100243627; called by muse, mutect2, varscan2
- BCL6 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.451); catalogued as rs375595181; called by muse, mutect2, varscan2
- BCL9L | c.4388del p.P1463Rfs*94 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs1555172524; called by mutect2, pindel, varscan2
- BCL9L | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100599862; called by muse, mutect2, varscan2
- BCORL1 | c.5042dup p.G1682Rfs*4 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | catalogued as rs768244116, COSV54407680; called by mutect2, varscan2
- BCR | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100006542; called by muse, mutect2, varscan2
- BCS1L | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.516); catalogued as COSV99829017; called by muse, mutect2, varscan2
- BEND5 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100884114; called by muse, mutect2, varscan2
- BICRA | c.2936C>G p.A979G | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs776041851, COSV67605216; called by muse, mutect2, varscan2
- BIRC6 | c.11890G>A p.V3964M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.975); catalogued as COSV101428306, COSV70203696; called by muse, mutect2, varscan2
- BIRC7 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99416765; called by muse, mutect2, varscan2
- BIRC7 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1174465355, COSV99416766; called by muse, mutect2, varscan2
- BLMH | c.645G>A p.E215= | Splice Region (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99913141; called by muse, mutect2, varscan2
- BLMH | c.553-1G>A p.X185_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as COSV55586422, COSV99913142; called by muse, mutect2, varscan2
- BMP15 | c.851G>A p.S284N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.052); catalogued as COSV99399374; called by muse, mutect2, varscan2
- BMPER | c.1496A>T p.N499I | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779636; called by muse, mutect2
- BMS1 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100996710; called by muse, mutect2, varscan2
- BOD1L1 | c.8525A>G p.Y2842C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); catalogued as COSV99239402; called by muse, mutect2, varscan2
- BOD1L1 | c.6350C>G p.A2117G | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV99239407; called by muse, mutect2, varscan2
- BOD1L1 | c.419A>T p.D140V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99239408; called by muse, mutect2, varscan2
- BPIFA1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV100845643; called by muse, mutect2, varscan2
- BPIFC | c.1402-1G>T p.X468_splice | Splice Site (SNP) | VAF 24/74 reads (32%) | catalogued as rs1340116550, COSV99322141; called by muse, mutect2, varscan2
- BPIFC | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100301068; called by muse, mutect2, varscan2
- BPTF | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs200853934, COSV100075004; called by muse, mutect2, varscan2
- BRD1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1479967915, COSV99349790; called by muse, mutect2, varscan2
- BRD2 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs759508036, COSV100875698; called by muse, mutect2, varscan2
- BRD3 | c.71dup p.E25Gfs*51 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD4 | c.2561A>G p.H854R | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99650700; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 7/17 reads (41%) | catalogued as rs749043197; called by mutect2, varscan2
- BRINP1 | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs773171289, COSV56292570, COSV99775502; called by muse, mutect2, varscan2
- BRINP3 | c.794G>A p.C265Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100818790; called by muse, mutect2, varscan2
- BRINP3 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV66542324; called by muse, mutect2, varscan2
- BRPF3 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100325878; called by muse, mutect2, varscan2
- BRWD1 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs760850324, COSV60901666; called by muse, varscan2
- BRWD3 | c.1630T>C p.C544R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100956077; called by muse, mutect2, varscan2
- BRWD3 | c.1406T>C p.F469S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100956078; called by muse, mutect2, varscan2
- BSDC1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100344754; called by muse, mutect2, varscan2
- BSN | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99608537; called by muse, mutect2, varscan2
- BSPRY | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs754285338, COSV100949528; called by muse, mutect2, varscan2
- BSX | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV100545237; called by muse, mutect2, varscan2
- BTBD10 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV99533629; called by muse, mutect2, varscan2
- BTBD16 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.357); catalogued as COSV99584811; called by muse, mutect2, varscan2
- BTBD9 | c.1117T>C p.S373P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100021862; called by mutect2, varscan2
- BTN3A1 | c.716A>G p.D239G | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs747919410, COSV99175818; called by muse, mutect2, varscan2
- BTN3A3 | c.883T>A p.Y295N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.454); catalogued as COSV99764893; called by muse, mutect2, varscan2
- BUB1B | c.1476G>A p.M492I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99806936; called by mutect2, varscan2
- C12orf42 | c.1009del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs771322722; called by pindel, varscan2
- C12orf42 | c.994T>A p.S332T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as COSV100172253; called by muse, varscan2
- C12orf66 | c.10T>G p.S4A | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs1225815466, COSV100320754; called by muse, mutect2, varscan2
- C16orf86 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99708209; called by muse, mutect2, varscan2
- C1QL3 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs1305027679, COSV100126670; called by muse, mutect2, varscan2
- C1QTNF5 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.485); catalogued as COSV100264815; called by muse, mutect2, varscan2
- C1QTNF9B | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as rs375679821, COSV65944630; called by muse, mutect2, varscan2
- C1S | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196562; called by muse, mutect2, varscan2
- C1orf174 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV100851778; called by muse, mutect2
- C1orf35 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs534724964, COSV55255540; called by muse, mutect2, varscan2
- C2orf69 | c.652A>G p.N218D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100178823; called by muse, mutect2, varscan2
- C3 | c.2050G>A p.G684S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.028); catalogued as rs201872466, COSV99836665; called by muse, varscan2
- C3 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV99836667; called by muse, mutect2, varscan2
- C3orf38 | c.76A>T p.I26F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100007407; called by muse, mutect2, varscan2
- C3orf62 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV100543035; called by muse, mutect2, varscan2
- C4orf19 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV99448578; called by muse, mutect2, varscan2
- C6 | c.1783del p.Q595Nfs*36 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs767886734; called by mutect2, pindel, varscan2
- C6orf15 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV99456879; called by muse, mutect2, varscan2
- C7 | c.429T>C p.G143= | Splice Region (SNP) | VAF 24/52 reads (46%) | catalogued as COSV100495843; called by muse, varscan2
- C7orf25 | c.586A>G p.N196D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV63274399; called by muse, mutect2, varscan2
- C7orf26 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs756236946, COSV100732912, COSV60420637; called by muse, mutect2, varscan2
- C7orf33 | c.88A>G p.S30G | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV100188805; called by muse, mutect2, varscan2
- C7orf50 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs774621441, COSV100657549; called by muse, mutect2, varscan2
- C9orf153 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100188658; called by muse, mutect2, varscan2
- C9orf72 | c.818A>G p.K273R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV101186518; called by muse, mutect2, varscan2
- C9orf78 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs1259238570, COSV100204334; called by muse, mutect2, varscan2
- CA11 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV99320646; called by muse, mutect2, varscan2
- CACHD1 | c.3704dup p.Q1236Sfs*23 | Frame Shift Ins (INS) | VAF 12/31 reads (39%) | catalogued as rs764948820; called by mutect2, varscan2
- CACNA1A | c.1726T>A p.S576T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100802466; called by muse, mutect2, varscan2
- CACNA1B | c.6976G>A p.A2326T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs369460375; called by muse, mutect2, varscan2
- CACNA1C | c.4270G>A p.A1424T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100219132; called by muse, mutect2, varscan2
- CACNA1C | c.6164A>G p.N2055S (on ENST00000399634 / NM_001167625.1; = p.N1984S on NM_000719.7) | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.021); catalogued as COSV100219134; called by muse, mutect2, varscan2
- CACNA1D | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV55458577; called by mutect2, varscan2
- CACNA1D | c.6335G>A p.R2112H (on ENST00000350061 / NM_001128840.3; = p.R2132H on NM_000720.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs895748125, COSV55438311; called by muse, mutect2, varscan2
- CACNA1E | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 30/53 reads (57%) | catalogued as COSV100702726; called by muse, varscan2
- CACNA1E | c.2031G>A p.M677I | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100702728; called by muse, mutect2, varscan2
- CACNA1G | c.4609G>A p.V1537M | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV100661853; called by muse, mutect2, varscan2
- CACNA1I | c.5623G>A p.E1875K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs766958362, COSV100360349; called by muse, mutect2, varscan2
- CACNA1S | c.389T>A p.V130D | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100755013; called by muse, mutect2, varscan2
- CACNG1 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs758950345, COSV99871677; called by muse, mutect2, varscan2
- CADPS2 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs772238734, COSV57359691; called by muse, mutect2, varscan2
- CAMK1D | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs754487170, COSV66611822; called by muse, mutect2, varscan2
- CAMLG | c.636del p.I213Yfs*26 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs755246634; called by mutect2, pindel, varscan2
- CAMSAP3 | c.3683T>C p.I1228T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99350755; called by muse, mutect2, varscan2
- CAMTA1 | c.1891A>G p.T631A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV100349693; called by muse, mutect2, varscan2
- CAP2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100012471; called by muse, mutect2, varscan2
- CAPS2 | c.1636T>C p.Y546H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100157774; called by muse, mutect2, varscan2
- CARD10 | c.1650G>A p.M550I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV99324971; called by muse, mutect2, varscan2
- CARD11 | c.2494A>G p.I832V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.175); catalogued as COSV100829191; called by muse, mutect2, varscan2
- CARD11 | c.1053C>G p.C351W | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.775); catalogued as COSV101210731; called by muse, mutect2, varscan2
- CARD14 | c.1700G>A p.S567N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.815); catalogued as rs370687430, COSV60125762; called by muse, mutect2, varscan2
- CARMIL1 | c.963G>A p.G321= | Splice Region (SNP) | VAF 43/89 reads (48%) | catalogued as rs764961384, COSV100277825; called by muse, mutect2, varscan2
- CASK | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.133); catalogued as COSV100587215; called by muse, mutect2, varscan2
- CASP14 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99693034; called by muse, mutect2, varscan2
- CASP8 | c.1438T>C p.*480Rext*? (on ENST00000432109 / NM_033355.3; = p.*497Rext*? on NM_001228.4) | Nonstop Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs761997594, COSV99630280; called by muse, varscan2
- CATSPER1 | c.1003A>G p.I335V | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100375966; called by muse, mutect2, varscan2
- CATSPER3 | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254122; called by mutect2, varscan2
- CATSPERB | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV99831168; called by muse, mutect2, varscan2
- CBLL2 | c.55T>C p.Y19H | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs755088322, COSV100081605; called by muse, mutect2, varscan2
- CBLN1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54653318; called by muse, mutect2, varscan2
- CBX2 | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs369432478, COSV99490875; called by muse, mutect2, varscan2
- CBX6 | c.476T>C p.I159T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99328133; called by muse, mutect2, varscan2
- CC2D2A | c.2131C>T p.Q711* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101052784; called by muse, mutect2, varscan2
- CCAR2 | c.551G>C p.R184P | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51516750, COSV99254598; called by muse, mutect2, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCBE1 | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101232828; called by muse, mutect2, varscan2
- CCDC103 | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99493300; called by muse, mutect2, varscan2
- CCDC120 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100900632; called by muse, mutect2, varscan2
- CCDC14 | c.1028C>T p.A343V (on ENST00000488653; = p.A295V on NM_022757.5) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV100113225; called by muse, mutect2, varscan2
- CCDC146 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV53553577, COSV99592612; called by muse, mutect2, varscan2
- CCDC160 | c.968A>T p.D323V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV66251710; called by muse, mutect2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC181 | c.766T>A p.L256I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100890321; called by muse, mutect2, varscan2
- CCDC181 | c.438T>A p.D146E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100890323; called by muse, mutect2
- CCDC22 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as rs782401247, COSV100873161; called by muse, varscan2
- CCDC40 | c.488A>G p.H163R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV99481768; called by muse, mutect2, varscan2
- CCDC40 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99481770; called by muse, mutect2, varscan2
- CCDC70 | c.151dup p.I51Nfs*72 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | catalogued as rs752919705; called by mutect2, varscan2
- CCDC77 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); catalogued as COSV99519874; called by muse, mutect2, varscan2
- CCDC85A | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339467; called by muse, mutect2, varscan2
- CCDC86 | c.568del p.R190Gfs*16 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs770211846; called by mutect2, pindel, varscan2
- CCDC87 | c.2122A>T p.K708* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100039994; called by muse, mutect2, varscan2
- CCDC88A | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99710469; called by muse, mutect2
- CCDC88B | c.3901G>A p.V1301M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1355835795, COSV57266318, COSV57266971; called by muse, mutect2, varscan2
- CCDC88C | c.3707C>T p.A1236V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs773164145, COSV101105650; called by muse, mutect2, varscan2
- CCN2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as COSV100915319; called by muse, mutect2, varscan2
- CCNB1 | c.1031T>A p.I344N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99841290; called by muse, mutect2, varscan2
- CCNB3 | c.4073A>G p.Y1358C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV99329093; called by muse, mutect2, varscan2
- CCND1 | c.61A>G p.N21D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.265); catalogued as rs766170770, COSV99919553; called by muse, mutect2, varscan2
- CCNE1 | c.1108C>T p.L370= | Splice Region (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99388402; called by muse, mutect2, varscan2
- CCNF | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1458095752, COSV99563630; called by muse, varscan2
- CCNF | c.2316A>G p.I772M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99563632; called by muse, mutect2, varscan2
- CCNG1 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 25/46 reads (54%) | catalogued as COSV100546737; called by muse, mutect2, varscan2
- CCNYL1 | c.1057C>T p.R353C (on ENST00000295414 / NM_001330218.2; = p.R283C on NM_152523.2) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.696); catalogued as rs758994523, COSV99775893; called by muse, varscan2
- CCT7 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV99240812; called by muse, mutect2, varscan2
- CD200 | c.304A>G p.T102A (on ENST00000473539 / NM_001004196.3; = p.T77A on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs752247110, COSV100238322; called by muse, mutect2, varscan2
- CD247 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs200420054, COSV100758376; called by muse, mutect2, varscan2
- CD300LG | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.077); catalogued as rs765955166, COSV99517427; called by muse, mutect2, varscan2
- CD320 | c.144C>T p.G48= | Splice Region (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100035816; called by muse, mutect2, varscan2
- CD3G | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99416693; called by muse, mutect2, varscan2
- CD46 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV100522911; called by muse, mutect2, varscan2
- CD48 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100924232, COSV63567965; called by muse, mutect2, varscan2
- CD55 | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as COSV100132428; called by muse, mutect2, varscan2
- CD6 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.336); catalogued as COSV100533036; called by muse, mutect2, varscan2
- CD7 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1429746468, COSV57067528; called by muse, varscan2
- CD82 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.494); catalogued as COSV99907571; called by muse, mutect2, varscan2
- CDADC1 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99212563; called by muse, mutect2, varscan2
- CDADC1 | c.539T>C p.L180S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99212564; called by muse, mutect2, varscan2
- CDAN1 | c.3662G>A p.G1221D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV99313891; called by muse, mutect2, varscan2
- CDC20B | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV99696924; called by muse, mutect2, varscan2
- CDC40 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV100309322; called by muse, mutect2, varscan2
- CDC40 | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100309323; called by muse, mutect2, varscan2
- CDC40 | c.1306A>G p.T436A | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100309328; called by muse, mutect2, varscan2
- CDC42BPB | c.4615A>G p.T1539A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as rs1216698851, COSV100775455; called by muse, mutect2, varscan2
- CDC42EP3 | c.152A>T p.D51V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99767870; called by muse, mutect2, varscan2
- CDC6 | c.1548G>T p.R516S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52929807; called by muse, mutect2, varscan2
- CDCA5 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV99297845; called by muse, mutect2, varscan2
- CDCP2 | c.672dup p.T225Hfs*91 | Frame Shift Ins (INS) | VAF 16/39 reads (41%) | catalogued as rs71066903; called by mutect2, pindel, varscan2
- CDH10 | c.2187del p.Y730Tfs*19 | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | catalogued as rs1273877423; called by mutect2, pindel, varscan2
- CDH10 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.392); catalogued as rs779851472, COSV52589267; called by muse, mutect2, varscan2
- CDH11 | c.1706T>C p.L569P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as COSV99218462; called by muse, mutect2, varscan2
- CDH12 | c.1515+2T>C p.X505_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV101202565; called by muse, mutect2, varscan2
- CDH13 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV99224464; called by muse, mutect2, varscan2
- CDH15 | c.1916T>C p.L639P | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99228409; called by muse, mutect2, varscan2
- CDH22 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867452804, COSV64836773; called by muse, mutect2, varscan2
- CDH4 | c.2269A>G p.K757E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV100848857; called by muse, mutect2, varscan2
- CDH6 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs201394958; called by muse, mutect2, varscan2
- CDHR1 | c.2251A>G p.I751V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100258893; called by muse, mutect2, varscan2
- CDHR2 | c.2363del p.G788Vfs*4 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs868286996; called by pindel, varscan2
- CDIPT | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV99570200; called by muse, mutect2, varscan2
- CDK12 | c.3177G>T p.E1059D | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV101420455; called by muse, mutect2, varscan2
- CDK13 | c.2353+2T>C p.X785_splice | Splice Site (SNP) | VAF 9/14 reads (64%) | catalogued as COSV99475539; called by muse, mutect2, varscan2
- CDK20 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100308083; called by muse, mutect2, varscan2
- CDK5RAP2 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100575465; called by muse, mutect2, varscan2
- CDKN1A | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.353); catalogued as rs753529000, COSV55191210; called by muse, mutect2, varscan2
- CDKN2A | c.407del p.G136Afs*10 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as COSV58684212; called by pindel, varscan2
- CDKN2A | c.385T>A p.Y129N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100446480, COSV58728095; called by muse, varscan2
- CDKN2A | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs767642535, CD062128, COSV58705361; ClinVar: uncertain significance; called by muse, varscan2
- CDRT1 | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99887584; called by muse, mutect2, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs759091263; called by mutect2, varscan2
- CDT1 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99967218; called by muse, mutect2, varscan2
- CDX2 | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.455); catalogued as COSV101122680; called by mutect2, varscan2
- CDYL2 | c.1147T>C p.Y383H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101629565; called by muse, mutect2, varscan2
- CEACAM18 | c.880T>C p.Y294H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101140382; called by muse, mutect2, varscan2
- CEACAM19 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1353309492, COSV100715452; called by muse, mutect2, varscan2
- CEACAM4 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs782116692, COSV55731143; called by muse, mutect2, varscan2
- CECR2 | c.3194C>T p.T1065M (on ENST00000342247 / NM_001290047.2; = p.T881M on NM_001290046.1) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.265); catalogued as rs778651502, COSV52845655; called by muse, mutect2, varscan2
- CELSR1 | c.7567A>G p.N2523D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV99418341; called by muse, mutect2, varscan2
- CELSR1 | c.4175A>G p.D1392G | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV99418343; called by muse, mutect2, varscan2
- CELSR1 | c.3895G>A p.V1299M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs559583570, COSV99418345; called by muse, mutect2, varscan2
- CELSR1 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99418348; called by muse, mutect2, varscan2
- CELSR2 | c.2183G>A p.G728D | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99603874; called by muse, mutect2, varscan2
- CEMIP | c.3553T>C p.F1185L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99586763; called by muse, mutect2, varscan2
- CEMP1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.011); catalogued as COSV99565859; called by muse, mutect2, varscan2
- CENPB | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100713441; called by muse, mutect2, varscan2
- CENPC | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99893948; called by muse, mutect2
- CENPF | c.2176T>C p.S726P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.575); catalogued as COSV100871697; called by muse, mutect2
- CENPL | c.154T>A p.C52S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100616351; called by muse, mutect2, varscan2
- CEP104 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs914907821, COSV65512999; called by muse, mutect2, varscan2
- CEP128 | c.2211+2T>G p.X737_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99824758; called by muse, mutect2, varscan2
- CEP164 | c.749G>A p.G250D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); catalogued as rs368668415, COSV54041798; called by muse, varscan2
- CEP164 | c.3296T>G p.V1099G | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV99633380; called by muse, mutect2, varscan2
- CEP192 | c.7384A>G p.N2462D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100381275; called by muse, mutect2
- CEP290 | c.4612G>A p.A1538T | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58357512; called by muse, mutect2, varscan2
- CEP350 | c.8984A>G p.Q2995R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV100854706; called by muse, mutect2, varscan2
- CEP72 | c.1246A>G p.T416A | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99374819; called by muse, mutect2, varscan2
- CEP85L | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV100874202; called by muse, mutect2, varscan2
- CERS1 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1161008712, COSV99896784; called by muse, mutect2, varscan2
- CES2 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs775667389, COSV57696750; called by muse, mutect2, varscan2
- CES5A | c.1003A>T p.I335F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99307564; called by muse, mutect2, varscan2
- CFAP161 | c.636G>A p.P212= | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as rs200582801, COSV99715476; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP299 | c.281T>C p.F94S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV100811683; called by muse, mutect2
- CFAP36 | c.271del p.H91Ifs*22 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | catalogued as COSV100170785; called by mutect2, pindel, varscan2
- CFAP52 | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99556704; called by muse, mutect2, varscan2
- CFAP65 | c.3212G>A p.R1071Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.255); catalogued as rs372695230; called by muse, mutect2, varscan2
- CFAP65 | c.305C>T p.A102V (on ENST00000341552 / NM_194302.4; = p.A37V on NM_152389.4) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99838337; called by muse, mutect2, varscan2
- CFAP77 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as rs868466074, COSV100545843; called by muse, mutect2, varscan2
- CFAP91 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs1037030638, COSV56346412; called by muse, mutect2, varscan2
- CFAP97 | c.306del p.K102Nfs*23 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs1305639008; called by mutect2, pindel, varscan2
- CFHR2 | c.255A>G p.R85= | Splice Region (SNP) | VAF 10/49 reads (20%) | catalogued as rs1406507757, COSV100804326; called by muse, varscan2
- CFHR2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV66381992; called by muse, mutect2, varscan2
- CFHR3 | c.607T>C p.C203R | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100807581; called by muse, mutect2, varscan2
- CGN | c.58A>T p.I20F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99642345; called by mutect2, varscan2
- CHAF1A | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.509); catalogued as rs532996643, COSV100011195; called by muse, mutect2, varscan2
- CHD1L | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV100787455; called by muse, mutect2, varscan2
- CHD2 | c.3718C>A p.P1240T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV101245274; called by muse, mutect2, varscan2
- CHD3 | c.929T>G p.V310G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV100391218, COSV57878469; called by muse, mutect2, varscan2
- CHD4 | c.5239T>C p.Y1747H (on ENST00000357008 / NM_001363606.2; = p.Y1758H on NM_001273.5) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58910581; called by muse, mutect2, varscan2
- CHD4 | c.3436A>G p.R1146G (on ENST00000357008 / NM_001363606.2; = p.R1159G on NM_001273.5) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58895872; called by muse, mutect2, varscan2
- CHD4 | c.2453G>A p.G818D (on ENST00000357008 / NM_001363606.2; = p.G831D on NM_001273.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100538067; called by muse, mutect2, varscan2
- CHD4 | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100538070; called by muse, mutect2, varscan2
- CHD5 | c.4313G>A p.R1438H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866772665, COSV99313659; called by muse, mutect2, varscan2
- CHD5 | c.2635del p.L879Ffs*15 | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | catalogued as COSV52414058; called by mutect2, pindel, varscan2
- CHD6 | c.2096T>A p.I699N | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100498294; called by muse, mutect2, varscan2
- CHD9 | c.5244A>G p.I1748M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99529180; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHFR | c.1147A>G p.N383D (on ENST00000432561 / NM_001161345.1; = p.N342D on NM_018223.2) | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99905326; called by muse, mutect2, varscan2
- CHIA | c.553G>A p.A185T (on ENST00000343320; = p.A77T on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100588676; called by muse, mutect2, varscan2
- CHIC1 | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV100998238; called by muse, mutect2, varscan2
- CHIC2 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV99816100; called by muse, mutect2, varscan2
- CHML | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); catalogued as COSV100087430, COSV59366682; called by muse, mutect2, varscan2
- CHML | c.200A>T p.D67V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV100087431; called by muse, mutect2
- CHPF2 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142607366; called by muse, mutect2, varscan2
- CHRM4 | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.99); catalogued as rs375771904; called by muse, mutect2, varscan2
- CHRNA10 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.165); catalogued as COSV51702909; called by muse, mutect2, varscan2
- CHRNA2 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs567044128, COSV99532244; ClinVar: uncertain significance; called by muse, mutect2
- CHRNA4 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV100937416; called by muse, mutect2, varscan2
- CHRNA7 | c.1172G>A p.G391D | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.506); catalogued as COSV100181228; called by muse, mutect2, varscan2
- CHRNB2 | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100872607; called by muse, mutect2, varscan2
- CHRNB4 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.148); catalogued as COSV99929370; called by muse, mutect2, varscan2
- CHST2 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58885500; called by muse, mutect2, varscan2
- CHST5 | c.358T>C p.S120P | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100291949; called by muse, mutect2, varscan2
- CHSY3 | c.1261A>T p.T421S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.349); catalogued as COSV100519119, COSV59278660; called by muse, mutect2, varscan2
- CILP2 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV99364700; called by muse, mutect2, varscan2
- CIT | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV55860625; called by muse, mutect2, varscan2
- CIZ1 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 59/146 reads (40%) | catalogued as COSV99476887; called by muse, mutect2, varscan2
- CKAP4 | c.1331A>T p.H444L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV100952457; called by muse, mutect2, varscan2
- CKLF-CMTM1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs372959958, COSV50451380; called by muse, mutect2, varscan2
- CLCA1 | c.2200G>A p.G734R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99322372; called by muse, mutect2, varscan2
- CLCA2 | c.1315A>G p.T439A | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV100991541, COSV65289038; called by muse, mutect2, varscan2
- CLCN5 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100260141; called by muse, mutect2, varscan2
- CLCNKB | c.1395del p.Y466Mfs*13 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as rs762878606; called by mutect2, pindel, varscan2
- CLDN11 | c.13T>C p.C5R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99291036; called by muse, mutect2, varscan2
- CLDN19 | c.394T>C p.C132R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99591645; called by muse, mutect2, varscan2
- CLDN25 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200887183, COSV101493602; called by muse, mutect2, varscan2
- CLDN7 | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100598145; called by muse, mutect2, varscan2
- CLIP1 | c.3646del p.R1216Efs*6 (on ENST00000620786 / NM_001247997.1; = p.R1205Efs*6 on NM_002956.2) | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs761972338; called by mutect2, pindel, varscan2
- CLIP1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs958782845, COSV100211757; called by muse, mutect2, varscan2
- CLN6 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99992617; called by muse, mutect2, varscan2
- CLN8 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100486051; called by muse, mutect2, varscan2
- CLPSL1 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1453248984, COSV100846309; called by muse, mutect2
- CLPX | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.448); catalogued as COSV100269493; called by muse, mutect2, varscan2
- CLSPN | c.3235T>C p.Y1079H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99230931; called by muse, mutect2, varscan2
- CLSPN | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758623904, COSV52055598; called by muse, mutect2, varscan2
- CLTCL1 | c.3608A>G p.D1203G | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99595082; called by muse, mutect2, varscan2
- CLTCL1 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs782319695, COSV99595083; called by muse, mutect2, varscan2
- CLUH | c.3772G>A p.A1258T (on ENST00000435359; = p.A1297T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV101425745; called by muse, mutect2, varscan2
- CLYBL | c.927+2T>C p.X309_splice | Splice Site (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100185123; called by muse, mutect2, varscan2
- CMPK2 | c.1078T>C p.Y360H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99878838; called by muse, mutect2, varscan2
- CMTM2 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216481; called by muse, mutect2, varscan2
- CNGA3 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55623379; called by muse, mutect2
- CNGA4 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101171805; called by muse, mutect2, varscan2
- CNGB1 | c.2114A>T p.D705V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99202561; called by muse, varscan2
- CNGB1 | c.2060A>G p.N687S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs766264215, COSV99202562; called by muse, varscan2
- CNKSR1 | c.932C>T p.A311V (on ENST00000374253 / NM_001297647.2; = p.A304V on NM_006314.3) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV100836738; called by muse, varscan2
- CNKSR2 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV101072718; called by muse, mutect2, varscan2
- CNN3 | c.262A>G p.N88D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100930938; called by muse, mutect2, varscan2
- CNNM1 | c.1235A>C p.K412T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV100763865; called by muse, mutect2, varscan2
- CNNM3 | c.1993A>G p.T665A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100562682; called by muse, mutect2, varscan2
- CNOT1 | c.6827A>T p.Y2276F | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99543179; called by muse, mutect2, varscan2
- CNOT11 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as COSV99179303; called by muse, mutect2, varscan2
- CNOT2 | c.1342T>C p.Y448H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99972638; called by muse, mutect2, varscan2
- CNOT2 | c.1498T>C p.Y500H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV99972641; called by muse, mutect2, varscan2
- CNRIP1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55150338; called by muse, mutect2, varscan2
- CNTFR | c.696G>A p.W232* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100667550; called by muse, mutect2
- CNTFR | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.959); catalogued as rs757157223, COSV100667551; called by muse, mutect2, varscan2
- CNTLN | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99264173; called by muse, mutect2, varscan2
- CNTN2 | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100085024; called by muse, mutect2, varscan2
- CNTN3 | c.2692A>G p.T898A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99724495; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTN6 | c.1774A>G p.I592V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV100610751; called by muse, mutect2, varscan2
- CNTNAP1 | c.2932T>C p.Y978H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.906); catalogued as COSV99226441; called by muse, mutect2, varscan2
- CNTNAP3 | c.3053A>G p.Y1018C | Missense Mutation (SNP) | VAF 76/666 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99904847; called by muse, varscan2
- CNTNAP3 | c.2457dup p.F820Lfs*3 | Frame Shift Ins (INS) | VAF 25/105 reads (24%) | catalogued as COSV99903854; called by mutect2, pindel, varscan2
- CNTNAP5 | c.3502G>A p.V1168I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375640846, CM1010519; called by muse, mutect2, varscan2
- COBL | c.121dup p.H41Pfs*31 | Frame Shift Ins (INS) | VAF 11/29 reads (38%) | catalogued as rs778516787; called by mutect2, varscan2
- COBLL1 | c.2298T>A p.D766E (on ENST00000392717; = p.D728E on NM_014900.5) | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.74); PolyPhen benign (0.058); catalogued as COSV99527942; called by muse, mutect2, varscan2
- COG1 | c.1471A>G p.S491G | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100245315; called by muse, mutect2, varscan2
- COG2 | c.2102A>G p.Y701C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.401); catalogued as COSV100794687; called by muse, mutect2, varscan2
- COL12A1 | c.7918G>A p.V2640I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.168); catalogued as rs775684324, COSV100486012; called by muse, mutect2, varscan2
- COL16A1 | c.4664G>T p.G1555V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99594513; called by muse, mutect2, varscan2
- COL17A1 | c.3394A>G p.S1132G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV100793174; called by muse, mutect2, varscan2
- COL18A1 | c.4334T>C p.V1445A (on ENST00000359759 / NM_130444.3; = p.V1210A on NM_030582.4) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as COSV100645258, COSV60589274; called by muse, mutect2, varscan2
- COL20A1 | c.166T>C p.Y56H | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100490605; called by muse, mutect2, varscan2
- COL20A1 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV100490608, COSV100491131; called by muse, mutect2, varscan2
- COL21A1 | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766667430, COSV99778608, COSV99778797; called by muse, mutect2, varscan2
- COL25A1 | c.297G>A p.Q99= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as COSV101211428; called by muse, mutect2, varscan2
- COL2A1 | c.3230G>A p.G1077D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61531070; called by muse, mutect2, varscan2
- COL4A1 | c.3425G>A p.G1142D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011186; called by muse, mutect2
- COL4A4 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100306878; called by muse, mutect2, varscan2
- COL5A1 | c.1727del p.P576Lfs*6 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs1488498065; called by mutect2, pindel, varscan2
- COL6A2 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV99385082; called by muse, mutect2, varscan2
- COL6A3 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV99798390; called by muse, mutect2, varscan2
- COL6A6 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650284; called by muse, mutect2, varscan2
- COL9A2 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs531953673, COSV65623802; called by muse, mutect2, varscan2
- COL9A2 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs184896618, COSV101025700; called by muse, mutect2, varscan2
- COL9A2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV101025701; called by muse, mutect2, varscan2
- COLEC11 | c.674T>C p.F225S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99363274; called by muse, mutect2, varscan2
- COLEC12 | c.2225T>C p.L742S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV101232073; called by muse, mutect2, varscan2
- COLGALT2 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.742); catalogued as COSV62728907; called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs370448328; called by muse, mutect2, varscan2
- COMMD5 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100295877; called by muse, mutect2, varscan2
- COMT | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs1164888098, COSV99258644; called by muse, mutect2, varscan2
- COPB1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV99999597, COSV99999954; called by muse, mutect2, varscan2
- COPS2 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100157252; called by muse, mutect2, varscan2
- COQ10A | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV100369976; called by muse, mutect2, varscan2
- COQ9 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1296776586, COSV99345805; called by muse, mutect2, varscan2
- COX10 | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99886503; called by muse, mutect2, varscan2
- CPED1 | c.623A>G p.Q208R | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100120758; called by muse, mutect2, varscan2
- CPED1 | c.2423A>G p.N808S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs200825080, COSV100120761; called by muse, mutect2, varscan2
- CPPED1 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99903190; called by muse, mutect2, varscan2
- CPSF6 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99879371; called by muse, mutect2, varscan2
- CPXCR1 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV99342219; called by muse, mutect2, varscan2
- CRB1 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100958892; called by muse, mutect2, varscan2
- CREB3 | c.707T>A p.V236D | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100147756; called by muse, mutect2, varscan2
- CREB3L2 | c.1493G>A p.S498N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV100381756, COSV100381923; called by muse, mutect2, varscan2
- CREB5 | c.137T>C p.F46S (on ENST00000357727 / NM_182898.4; = p.F39S on NM_004904.3) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100744692; called by muse, mutect2, varscan2
- CREM | c.482T>C p.I161T (on ENST00000429130; = p.I112T on NM_001881.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV100415233; called by muse, varscan2
- CRIM1 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99753422; called by muse, mutect2, varscan2
- CRIM1 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.667); catalogued as rs1173656893, COSV54858684; called by muse, mutect2, varscan2
- CRISPLD1 | c.1062T>A p.D354E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100082018; called by muse, mutect2, varscan2
- CRISPLD2 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99295672; called by muse, mutect2, varscan2
- CROCC | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.913); catalogued as COSV100978234; called by muse, mutect2, varscan2
- CROCC | c.1586A>G p.H529R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.099); catalogued as COSV100978235; called by muse, mutect2, varscan2
- CROCC | c.4823G>A p.S1608N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV100978236; called by muse, mutect2, varscan2
- CRTAM | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV99912017; called by muse, mutect2, varscan2
- CRTC1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1171988042, COSV100119327, COSV58723376; called by muse, mutect2, varscan2
- CRTC2 | c.1675-1G>A p.X559_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100339071; called by muse, mutect2
- CRYBG1 | c.2122A>G p.S708G | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100954474; called by muse, mutect2, varscan2
- CRYZL1 | c.629T>G p.L210W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99280964; called by muse, mutect2
- CSAD | c.925G>A p.A309T (on ENST00000444623 / NM_001244705.2; = p.A336T on NM_015989.5) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV99914776; called by muse, mutect2, varscan2
- CSF1R | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs201569135; ClinVar: benign; called by muse, mutect2, varscan2
- CSF3 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99842439; called by muse, mutect2, varscan2
- CSKMT | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100649126; called by muse, mutect2, varscan2
- CSMD2 | c.5885C>T p.P1962L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99590149; called by muse, mutect2, varscan2
- CSMD2 | c.3010G>A p.A1004T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765882833, COSV99590153; called by muse, mutect2, varscan2
- CSMD2 | c.2740A>T p.S914C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99590154; called by muse, mutect2, varscan2
- CSMD3 | c.8122C>T p.R2708* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as rs773340701, COSV52214384; called by muse, mutect2, varscan2
- CSMD3 | c.3194-1G>A p.X1065_splice (on ENST00000297405 / NM_001363185.1; = p.X961_splice on NM_052900.3) | Splice Site (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99834827; called by muse, mutect2, varscan2
- CSNK1A1 | c.559T>C p.Y187H | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99939495; called by muse, mutect2, varscan2
- CSNK1G1 | c.532A>G p.K178E | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV100274166; called by muse, mutect2, varscan2
- CSNK1G1 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100274167; called by muse, mutect2
- CSNK1G2 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99729915; called by muse, mutect2, varscan2
- CSPP1 | c.373A>T p.I125F (on ENST00000676605; = p.I84F on NM_024790.6) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV99138584; called by muse, mutect2, varscan2
- CSRNP1 | c.911A>C p.Q304P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV99826893; called by muse, mutect2, varscan2
- CSTF2T | c.1678A>G p.S560G | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV100484203; called by muse, mutect2, varscan2
- CTDP1 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99310575; called by muse, mutect2, varscan2
- CTDP1 | c.1633G>A p.G545S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as rs1222942783, COSV99310629; called by muse, mutect2, varscan2
- CTH | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61009962; called by muse, mutect2, varscan2
- CTNNA3 | c.1708A>G p.N570D | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101049391; called by muse, mutect2, varscan2
- CTNND2 | c.3556A>G p.T1186A | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100476731; called by muse, mutect2, varscan2
- CTNND2 | c.2059A>T p.I687F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100476734; called by muse, mutect2, varscan2
- CTNND2 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV100476737, COSV58871230; called by muse, mutect2, varscan2
- CTPS2 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100826852; called by muse, varscan2
- CTR9 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100797367; called by muse, mutect2, varscan2
- CTR9 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761302085, COSV63728050; called by muse, mutect2, varscan2
- CTR9 | c.3335G>A p.S1112N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); catalogued as COSV100797368; called by muse, mutect2, varscan2
- CTSL | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100446659; called by muse, mutect2, varscan2
- CUBN | c.10423C>T p.P3475S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64710104; called by muse, mutect2, varscan2
- CUL3 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100024267; called by muse, mutect2
- CUL4B | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as COSV60686142; called by muse, mutect2, varscan2
- CUL9 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.051); catalogued as COSV99335427; called by muse, mutect2, varscan2
- CUL9 | c.4043G>A p.R1348H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs762030908, COSV52728844; called by muse, mutect2, varscan2
- CUX1 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.158); catalogued as COSV52913679; called by muse, mutect2, varscan2
- CXCR3 | c.20A>T p.D7V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV101031629; called by muse, mutect2, varscan2
- CXorf58 | c.168T>A p.H56Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV101002990; called by muse, mutect2, varscan2
- CYFIP2 | c.3641A>G p.D1214G (on ENST00000616178 / NM_001291722.2; = p.D1189G on NM_014376.4) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100556914; called by muse, mutect2, varscan2
- CYP11A1 | c.993G>A p.T331= | Splice Region (SNP) | VAF 15/41 reads (37%) | catalogued as rs565170516, COSV99166017; called by muse, mutect2, varscan2
- CYP1A1 | c.1211_1212insC p.R405Afs*13 | Frame Shift Ins (INS) | VAF 21/64 reads (33%) | catalogued as COSV101122308; called by mutect2, pindel, varscan2
- CYP1B1 | c.745T>C p.Y249H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.583); catalogued as COSV99572690; called by muse, mutect2, varscan2
- CYP1B1 | c.164T>C p.F55S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as rs965853036, COSV99572691; called by muse, mutect2
- CYP21A2 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.269); catalogued as COSV100925832; called by muse, mutect2, varscan2
- CYP2B6 | c.1433G>C p.G478A | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV100137571; called by muse, mutect2, varscan2
4,710 further variants in this file (3,205 protein-altering or splice-affecting, 1,358 silent, 147 other) are not listed here.
